CCDI case PBBVJN — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Bones, joints and articular cartilage of other and unspecified sites.
https://portal.gdc.cancer.gov/cases/daf53208-641b-46ff-a49b-07be6559a64b

Demographics
Sex at birth: male; Ethnicity: hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Papillary carcinoma, NOS: ICD-O-3 morphology code: 8050/3; Tissue or organ of origin: Head, face or neck, NOS; Age at diagnosis: 22.2 years (8,120 days).

Biospecimens (3 samples)
- Sample 0DIABY: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DIAC0: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DIACF: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
